Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T8, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T8-01A (Primary Tumor).

**Pathology
port**

P

DOB:
Physician:

Sex: F

Accession:

Collected

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA IN RIGHT LOBE (3.8 CM).
PAPILLARY THYROID CARCINOMA IN LEFT LOBE (LESS THAN 0.1 CM).
Definitive lymphovascular invasion is not identified.
Margins grossly free of tumor.

Entire report and diagnosis completed by I

*ICD-O-3
carcinoma, papillary, thyroid
8260/3*

*Site: thyroid, NOS
C73.9*

44-12 RD

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy product consisting of a right lobe (3.5 x 1.5 x 1.0 cm), unremarkable isthmus (1.0 x 1.0 x 0.3 cm), and the enlarged left lobe (4.3 x 3.5 x 3.0 cm).

A dominant nodule (3.8 x 3.0 x 3.0 cm) is identified in the left upper lobe laterally. The tumor has a thick capsule (1.0 mm in thickness), which has a tan-gray papillary and granular appearance with central cystic changes. The capsule is intact. The remaining thyroid tissue is tan-black, gelatinous and unremarkable. The isthmus and the right lobe are grossly unremarkable without obvious nodularity.

SECTION CODE: The left lobe is entirely submitted from superior to inferior in A1-A14 (tumor in A1-A12; normal tissue in A13-A14); A15, isthmus entirely submitted; A16-A18, right lobe superior to inferior.

Representative sections of the tumor and normal tissue are submitted to tumor bank.

CLINICAL HISTORY

Papillary thyroid cancer.

(R) lobe - normal tissue

(L) lobe - unifocal tumor

SNOMED CODES

T-B6000, M-80503

"Some tests reported here may have been developed and performance characteristics determined by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Source: NCI Genomic Data Commons file b8321521-d947-4e6a-817b-8a9cbd5cfeb7 (TCGA-EL-A3T8.D4D61A70-B4EA-4BAA-9C53-C5AF927D6FD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).